Surgical pathology report (de-identified scan), TCGA case TCGA-22-5474, project TCGA-LUSC (Lung Squamous Cell Carcinoma), tissue source site Mayo Clinic - Rochester, specimen TCGA-22-5474-01A (Primary Tumor).

[REDACTED]

[REDACTED] Surgical Pathology

[REDACTED] TCGA-22-5474

DIAGNOSIS:

Lung, left upper lobe, wedge resection: Grade 3 (of 4) squamous cell carcinoma forming a 2.0 x 1.8 x 1.8 cm mass arising in the background of usual interstitial pneumonia. The tumor invades into visceral pleura. The tumor is completely excised and extends to within 1 millimeter from stapled surgical margin.

Lymph nodes, superior and inferior mediastinal, excision: Multiple superior mediastinal (9 right lower paratracheal), inferior mediastinal (7 subcarinal) lymph nodes are negative for tumor.

[REDACTED]

Source: NCI Genomic Data Commons file 2b318443-f7b5-4f98-8d5b-1b425bad9a93 (TCGA-22-5474.E0BF9B86-3D7E-4A37-9545-B74DD999E128.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).